Gene-level copy-number profile of tumor specimen ALCH-AEYV-TTP1-A from ALCHEMIST case ALCH-AEYV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 63.9 years (23,348 days).
Specimen ALCH-AEYV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5af64b95-a35b-40b4-b90d-e9551d57ece4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEYV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/1697175e-aee4-495e-a060-8b3f9992d18b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 4,165; copy number 2: 50,620; copy number 3: 2,607; copy number 4: 895; copy number 5: 61; copy number 6: 2; copy number 7: 3; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:90,261,414–90,261,708, 1 gene: HSPE1P19.
- chr6:86,897,118–86,897,683, 2 genes: AL157777.1, AL157777.2.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr9:61,615,835–61,627,683, 1 gene: FAM242D.
- chr9:61,665,579–61,666,386, 1 gene: AL935212.2.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–2): CRB2.
- chr9:123,402,525–123,493,156, 3 genes (within-gene range 0–2): MIR601, MIR7150, AL445489.1.
- chr11:70,477,277–70,604,859, 2 genes (within-gene range 0–1): AP001271.1, AP001271.2.
- chr11:70,646,165–70,647,562, 1 gene (within-gene range 0–1): SHANK2-AS2.
- chr16:89,737,549–89,871,319, 2 genes (within-gene range 0–4): FANCA, SPIRE2.
- chr17:66,964,707–67,033,398, 3 genes: CACNG4, AC005544.1, AC005544.2.
- chr18:14,877,611–14,890,086, 2 genes: LINC01906, FGF7P1.
- chr18:14,946,267–15,006,352, 5 genes: LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 68 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:171,941,607–171,996,871, 1 gene, copy number 5: AC055714.1.
- chr5:58,198–1,634,005, 60 genes, copy number 5: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2.
- chr22:18,361,820–18,391,105, 2 genes, copy number 6: FAM230J, AC011718.1.
- chr22:18,527,802–18,611,919, 5 genes, copy number 7–9: TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3.

Autosomal genes at a single copy (total copy number 1): 2,927. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
